Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A230, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A230-01A (Primary Tumor).

[page 1 of 4]
HPV/A Discrepancy		☒

Specimen Description

ICD-O-3

Carcinoma, papillary thyroid 8260/3
Site: thyroid C73.9 lw 4/8/11

Surgical Pathology Report

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

*****Clinical History*****

Patient history: Thyroid CA.

*****Final Pathologic Diagnosis*****

- A. Left thyroid lobe, excision:
- Papillary thyroid carcinoma (see synoptic report).
- Hashimoto's thyroiditis.
- B. Right thyroid lobe, excision:
- Hashimoto's thyroiditis.
- Lymph node (1/1) with microscopic subcapsular focus of metastatic papillary carcinoma.
- C. Soft tissue overlying anterior cricoid, excision:
- Lymph nodes (2/2) involved with microscopic foci of metastatic carcinoma.

Electronically Signed By
[REDACTED]
[REDACTED]

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: Total thyroidectomy.

Tumor location: Left lobe.

Tumor size: 4.4 x 4.0 x 2.2 cm.

Histologic type: Papillary carcinoma.

Tumor grade: Well-differentiated.

Lymphatic/vascular invasion: No.

Capsular invasion: No.

Tumor extent:

Confined to the thyroid: Yes.

Multifocal: No.

Invasion of thyroid cartilage or hyoid bone: No.

Infiltration of adjacent structures: No.

Lymph nodes:

[page 2 of 4]
Sex: F

Specimen Description

Surgical Pathology Report

*****Clinical History*****

Patient history: Thyroid CA.

*****Final Pathologic Diagnosis*****

Left thyroid lobe, excision:

Papillary thyroid carcinoma (see synoptic report).
Hashimoto's thyroiditis.

Right thyroid lobe, excision:

- Hashimoto's thyroiditis.
- Lymph node (1/1) with microscopic subcapsular focus of
metastatic papillary carcinoma.

Soft tissue overlying anterior cricoid, excision:

- Lymph nodes (2/2) involved with microscopic foci of metastatic
carcinoma.

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: Total thyroidectomy.

Tumor location: Left lobe.

Tumor size: 4.4 x 4.0 x 2.2 cm.

Histologic type: Papillary carcinoma.

Tumor grade: Well-differentiated.

Lymphatic/vascular invasion: No.

Capsular invasion: No.

Tumor extent:

Confined to the thyroid: Yes.

Multifocal: No.

Invasion of thyroid cartilage or hyoid bone: No.

Infiltration of adjacent structures: No.

[page 3 of 4]
Lymph nodes:

Total number examined: 3

Number positive: 3

Number negative: 0

Extranodal extension: No.

Additional pathologic findings: Hashimoto's thyroiditis.

Comments: >

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

Left thyroid lobe, thyroid CA?, stitch=superior pole: (FROZEN SECTION PERFORMED)

- Papillary thyroid carcinoma

Examining pathologist

*****SPECIMEN(S) RECEIVED:*****

Thyroid, REG

Thyroid, REG

Soft tissue

*****GROSS DESCRIPTION:*****

The specimens are received in three properly labeled containers, one of which is submitted for frozen section, with the patient's name and accession number.

The specimen is designated "left thyroid lobe, thyroid CA?, stitch=superior pole" and consists of a 37.2 gram thyroid lobe measuring 5.7 x 4.2 x 3.2 cm that is oriented with a stitch designating superior pole. There are no lymph nodes or parathyroid glands and the capsule is inked black. The isthmic edge is inked yellow and cut section reveals a 4.4 x 4.0 x 2.2 cm thinly encapsulated nodule. The nodule abuts the capsular surface and is 0.2 cm from the isthmic edge. The nodule is composed of tan friable tissue with focal areas of hemorrhage. The uninvolved adjacent thyroid parenchyma is tan-pink to red-brown. A frozen section was performed and cassette AF1 is resubmitted as received. (P) RS
6

Summary of Cassettes: AF1, nodule, frozen section; A1-2, nodule and isthmic edge, perpendicular; A3, nodule and thyroid capsule, perpendicular; A4, nodule and adjacent uninvolved thyroid parenchyma; A5, uninvolved thyroid parenchyma

The specimen is designated "right thyroid lobe, stitch=superior pole" and consists of an 11.7 gram thyroid lobe that measures 5.0 x 4.0 x 1.6 cm. The capsular surface is inked black and the isthmic edge is inked

[page 4 of 4]
yellow. There is one possible lymph node identified measuring 0.6 cm in greatest dimension. Cut section through the thyroid reveals two areas of nodularity measuring 0.4 x 0.3 x 0.3 cm and 1.7 x 1.0 x 0.9 cm. Both of these areas are located in the inferior half of the lobe and are 0.8 and 1.1 cm from the isthmic edge, respectively. RS 5

Summary of Cassettes: B1, isthmic edge, shave; B2-3, larger nodular area; B4, smaller nodular area; B5, one lymph node

■ The specimen is designated "mass overlying anterior cricoid" and consists of two tan-pink nodes that measure 0.7 and 1.2 cm in greatest dimension. The larger node is bisected and reveals dark pink homogeneous rubbery tissue. TE 2

Summary of Cassettes: C1, larger node, bisected; C2, smaller node

Lab Use Only: ■

Gross description by: ■

■
Top of Page

Source: NCI Genomic Data Commons file 3ad2d20b-84b8-4bd6-9bdf-6a9eb590d189 (TCGA-FE-A230.376056EE-C698-481C-8B30-4489F3C75D58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).